HCMI case HCM-BROD-0762-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Fibromatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/509a9942-11da-479b-b38a-2ca2a30b5134

Demographics
Sex at birth: female; Year of birth: 2001.

Diagnoses (1)
1. Abdominal fibromatosis: ICD-O-3 morphology code: 8822/1; ICD-10 code: C49.9; Tissue or organ of origin: Abdomen, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 15.9 years (5,799 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate + Vinblastine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1 day; Days to treatment end: 313 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 5 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate + Vinblastine; Treatment intent type: Neoadjuvant; Days to treatment start: 183 days.
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Days to follow up: 1,024 days (2.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-BROD-0762-C49-01A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0762-C49-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-BROD-0762-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 19.
